Somatic mutation profile of tumor specimen MP2PRT-PATDGD-TMP1-A (aliquot MP2PRT-PATDGD-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATDGD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,235 days).
Specimen MP2PRT-PATDGD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 629cc748-a456-4310-be03-78b79c48a584.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDGD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDGD-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6289a049-7ce5-45a1-a509-485fa52ab9a1

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 2, Splice Region 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D1B | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs959087099; called by muse, mutect2, varscan2
- CRY1 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 70/314 reads (22%) | catalogued as rs1393545119; called by muse, mutect2, varscan2
- FAM131C | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 145/496 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747744990, COSV65154299; called by muse, mutect2
- PCDHB3 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV50589763; called by muse, mutect2, varscan2
- PNMA8A | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 16/620 reads (3%) | catalogued as COSV58135677; called by muse, mutect2
- SMG1 | c.4718C>T p.S1573F | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs377080801; called by muse, mutect2, varscan2
- UNC5D | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 25/638 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV54840744; called by muse, mutect2
- ZNF354C | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 102/541 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.503); catalogued as rs1197359943; called by muse, mutect2, varscan2
- AC092442.1 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 95/400 reads (24%) | called by muse, mutect2, varscan2
- CCDC197 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- CDC25B | c.1258-1G>A p.X420_splice (on ENST00000245960 / NM_021873.3; = p.X406_splice on NM_004358.4) | Splice Site (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- CYP11B2 | c.1119G>T p.L373F | Missense Mutation (SNP) | VAF 138/519 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM71E2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 80/305 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MAP1A | c.5299C>A p.L1767I | Missense Mutation (SNP) | VAF 19/606 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2
- MEAF6 | c.90G>C p.A30= | Splice Region (SNP) | VAF 76/355 reads (21%) | called by muse, mutect2, varscan2
- MINAR1 | c.2386C>T p.H796Y | Missense Mutation (SNP) | VAF 23/847 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- NLRP8 | c.2909G>T p.C970F | Missense Mutation (SNP) | VAF 89/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SEL1L2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SOWAHA | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 306/893 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNNI3K | c.2096T>C p.I699T | Missense Mutation (SNP) | VAF 85/462 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNXB | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 50/1150 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.431); called by muse, mutect2
- UTP14A | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 117/345 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNJL | c.1008C>T p.L336= | Silent (SNP) | VAF 38/758 reads (5%) | catalogued as rs750898193, COSV57444734; called by muse, mutect2
- COL2A1 | c.2568G>A p.Q856= | Silent (SNP) | VAF 160/616 reads (26%) | catalogued as rs932099004; called by muse, mutect2, varscan2
- IGSF1 | c.2718C>T p.L906= | Silent (SNP) | VAF 19/527 reads (4%) | called by muse, mutect2
- LRP1 | c.6601C>T p.L2201= | Silent (SNP) | VAF 35/988 reads (4%) | called by muse, mutect2
- POU5F1 | c.141C>T p.I47= | Silent (SNP) | VAF 32/1068 reads (3%) | catalogued as rs766077489; called by muse, mutect2
- TTC34 | c.285C>T p.G95= | Silent (SNP) | VAF 204/794 reads (26%) | catalogued as rs539680089; called by muse, mutect2, varscan2
- TTN | c.18138C>T p.T6046= (on ENST00000591111; = p.T5119= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/486 reads (3%) | catalogued as COSV100608806; called by muse, mutect2
- MLIP | c.613-12006C>G | Intron (SNP) | VAF 15/508 reads (3%) | called by muse, mutect2
